Somatic mutation profile of tumor specimen TCGA-AJ-A3EK-01A (aliquot TCGA-AJ-A3EK-01A-11D-A19Y-09) from TCGA case TCGA-AJ-A3EK, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 53.7 years (19,609 days).
Specimen TCGA-AJ-A3EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfa245ce-05c6-4e09-a645-e53d0b0f7a83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A3EK-11A (Solid Tissue Normal), aliquot TCGA-AJ-A3EK-11A-11D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cefae286-03d0-49fc-8b09-38f57fd87a2f

The open-access MAF lists 6,610 somatic variants for this specimen: 4,940 protein-altering or splice-affecting, 1,519 silent, 151 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4,306, Silent 1,519, Nonsense Mutation 343, Splice Site 115, Intron 66, Frame Shift Ins 65, Frame Shift Del 63, Splice Region 41, RNA 37, 3'UTR 20, 5'Flank 12, 5'UTR 9.

Variants (750 of 6,610; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- CARD11 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 26/59 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748839211, COSV67798212; called by muse, mutect2, varscan2
- CHD2 | c.522del p.V175* | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs748694853; ClinVar: likely pathogenic; called by mutect2, varscan2
- CNGB3 | c.1285del p.S429Lfs*9 | Frame Shift Del (DEL) | VAF 19/65 reads (29%) | catalogued as rs776896038; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTCF | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs879255516, CM136457, COSV50463702; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DYRK1A | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1057518204, CM162102, COSV100117767, COSV58296087; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EMD | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs148515772, COSV100877369; ClinVar: likely pathogenic / likely benign; called by muse, mutect2, varscan2
- EPCAM | c.491+1G>A p.X164_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as rs606231203, CS083989, COSV55392567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FGFR1 | c.1042G>A p.G348R (on ENST00000447712 / NM_023110.3; = p.G346R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886037634, CM103835, COSV100248113; ClinVar: pathogenic / risk factor; called by muse, mutect2, varscan2
- FGFR2 | c.1647T>G p.N549K | Missense Mutation (SNP) | VAF 45/134 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913476, COSV60638757, COSV60639738; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KDM5C | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs199422238, CM080420, COSV64763624; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.1802G>T p.R601L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV50266847; called by muse, mutect2, varscan2
- KEAP1 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV50287934; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MTM1 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs587783847, CM970989, COSV60334206; ClinVar: pathogenic; called by muse, mutect2
- MTOR | c.6644C>A p.S2215Y | Missense Mutation (SNP) | VAF 28/68 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.2672dup p.N891Kfs*2 | Frame Shift Ins (INS) | VAF 52/166 reads (31%) | catalogued as rs763860580; ClinVar: pathogenic; called by mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- NBEA | c.6637C>T p.R2213* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as rs878853169, COSV59803600; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2537C>A p.A846D | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1555614229, CM143344, COSV100646962; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.930C>T p.G310= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs745814294, CM154996, CS155347, COSV99770460; ClinVar: pathogenic; called by mutect2, varscan2
- P3H1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as rs140468248, COSV99355190; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 55/148 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as rs1114167674, CM110151, COSV64293312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4999G>A p.V1667I (on ENST00000333535 / NM_198056.3; = p.V1666I on NM_000335.5) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.87); catalogued as rs199473293, CM015375, COSV61140060; ClinVar: not provided / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.21148C>T p.R7050* (on ENST00000367255 / NM_182961.4; = p.R6979* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | catalogued as rs763325410, COSV99563110; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TK2 | c.220C>T p.R74W (on ENST00000299697; = p.R130W on NM_004614.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs281865493, CM074600, COSV55281306; ClinVar: pathogenic; called by muse, varscan2
- TMEM67 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as rs751517725, COSV60036110; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3731C>T p.A1244V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV100588657; called by muse, mutect2, varscan2
- A2ML1 | c.3490G>A p.A1164T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100228910; called by muse, mutect2, varscan2
- A4GALT | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs370246921, COSV99966651; called by muse, mutect2, varscan2
- A4GNT | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.36); catalogued as rs1290424588, COSV99367840; called by muse, mutect2
- AADAC | c.256T>G p.F86V | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99233231; called by muse, mutect2, varscan2
- AADACL3 | c.1220T>C p.L407P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60198705; called by muse, mutect2, varscan2
- AAGAB | c.218T>G p.I73S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV99971890; called by muse, mutect2, varscan2
- AAK1 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs761406931, COSV101117255; called by muse, mutect2, varscan2
- AAR2 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100299283; called by muse, mutect2, varscan2
- AARS1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV99933472; called by muse, mutect2, varscan2
- AARS2 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55117757; called by muse, mutect2, varscan2
- AASDH | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV52705847, COSV99221215; called by muse, mutect2, varscan2
- AASS | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1004656242, COSV100741774; called by muse, mutect2, varscan2
- ABCA1 | c.5059C>A p.L1687M | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); catalogued as COSV101036909; called by muse, mutect2
- ABCA1 | c.3604C>T p.H1202Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs751117806, COSV101036915; called by muse, mutect2, varscan2
- ABCA10 | c.2363T>C p.I788T | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV99288593; called by muse, mutect2, varscan2
- ABCA10 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV52219089, COSV52231354, COSV99288594; called by muse, mutect2, varscan2
- ABCA2 | c.5491G>A p.V1831M (on ENST00000614293; = p.V1801M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99686651; called by muse, mutect2, varscan2
- ABCA5 | c.1047A>C p.E349D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); catalogued as COSV101201130; called by muse, mutect2, varscan2
- ABCA5 | c.307+1G>A p.X103_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101201131; called by muse, mutect2
- ABCA6 | c.1171G>T p.G391* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99446428; called by muse, mutect2
- ABCA7 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.196); catalogued as COSV99565718; called by muse, mutect2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as rs1222604496, COSV55945529; called by muse, mutect2, varscan2
- ABCB9 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs778974080, COSV54892053; called by muse, mutect2, varscan2
- ABCC1 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs754876461, COSV100579491; called by muse, mutect2, varscan2
- ABCC10 | c.4223C>T p.A1408V (on ENST00000372530 / NM_001198934.2; = p.A1380V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767201; called by muse, mutect2, varscan2
- ABCC11 | c.2750G>A p.G917D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966893173, COSV100750742; called by muse, mutect2, varscan2
- ABCC11 | c.2424A>G p.I808M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.091); catalogued as rs1287084860, COSV100750743; called by muse, mutect2, varscan2
- ABCC11 | c.2103G>T p.Q701H | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100750744; called by muse, mutect2, varscan2
- ABCC2 | c.2444G>A p.R815Q | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV64984964; called by muse, mutect2, varscan2
- ABCC2 | c.4133C>T p.T1378I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473452859, COSV64985368; called by muse, mutect2, varscan2
- ABCC6 | c.4286C>T p.T1429I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374236964; called by muse, mutect2, varscan2
- ABCD2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752270059, COSV100429415; called by muse, mutect2, varscan2
- ABCD3 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.069); catalogued as rs538746918, COSV100238879; called by muse, mutect2, varscan2
- ABCD4 | c.199T>C p.Y67H | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100084262; called by muse, mutect2, varscan2
- ABCD4 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs972140495, COSV100084263; called by muse, mutect2, varscan2
- ABCF1 | c.895G>A p.E299K (on ENST00000326195 / NM_001025091.2; = p.E261K on NM_001090.3) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV100400822; called by muse, mutect2, varscan2
- ABCF1 | c.989G>A p.R330H (on ENST00000326195 / NM_001025091.2; = p.R292H on NM_001090.3) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as COSV100400823; called by muse, mutect2, varscan2
- ABCG2 | c.1445G>A p.R482K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); catalogued as COSV99419192; called by muse, mutect2, varscan2
- ABCG5 | c.1740C>A p.F580L | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53184368, COSV99571165; called by muse, mutect2, varscan2
- ABCG8 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.113); catalogued as rs1302267533, COSV99699772; called by muse, mutect2
- ABHD17B | c.486A>C p.E162D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV100330203; called by muse, mutect2, varscan2
- ABHD4 | c.945T>G p.I315M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99360515; called by muse, mutect2, varscan2
- ABI2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as rs1208544228, COSV99651763; called by muse, mutect2, varscan2
- ABL2 | c.713T>C p.F238S (on ENST00000502732 / NM_007314.4; = p.F223S on NM_005158.5) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772708; called by muse, mutect2, varscan2
- ABRA | c.318G>T p.K106N | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV100357551, COSV61732577; called by muse, mutect2, varscan2
- ABT1 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs782145465, COSV99223212; called by muse, mutect2, varscan2
- AC093155.3 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | PolyPhen benign (0.003); catalogued as COSV100986541; called by muse, mutect2, varscan2
- AC098582.1 | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99985572; called by muse, mutect2, varscan2
- AC100868.1 | c.1261G>T p.G421* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | catalogued as COSV99225995; called by muse, mutect2, varscan2
- ACAA2 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99551829; called by muse, mutect2, varscan2
- ACACB | c.3732G>T p.E1244D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100622837; called by muse, mutect2, varscan2
- ACADS | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs773564658, COSV54370654; called by muse, mutect2, varscan2
- ACAN | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as rs376179210; called by muse, mutect2, varscan2
- ACAP2 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1371250867, COSV100462039; called by muse, mutect2, varscan2
- ACBD5 | c.1255G>A p.E419K (on ENST00000375888 / NM_001352568.1; = p.E410K on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.54); catalogued as rs764818384, COSV65520886; called by muse, mutect2, varscan2
- ACCSL | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV101122185; called by muse, mutect2, varscan2
- ACCSL | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs749322101, COSV101122186; called by muse, mutect2, varscan2
- ACER1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100034014; called by muse, mutect2, varscan2
- ACKR2 | c.1113G>T p.E371D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); catalogued as COSV99825507; called by muse, mutect2
- ACKR4 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 39/169 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1398393923, COSV51442163; called by muse, mutect2, varscan2
- ACLY | c.1749G>T p.M583I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100709679; called by muse, mutect2, varscan2
- ACLY | c.1638A>C p.K546N | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100709680; called by muse, mutect2, varscan2
- ACO1 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV59380910; called by muse, mutect2, varscan2
- ACO1 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764953534, COSV100008100; called by muse, mutect2, varscan2
- ACOT1 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100233413; called by muse, mutect2, varscan2
- ACOX2 | c.1288T>G p.L430V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100250150; called by muse, mutect2
- ACOX2 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs941553281, COSV57150425, COSV57151338; called by muse, mutect2, varscan2
- ACOX3 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV100711947; called by muse, mutect2, varscan2
- ACSBG1 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99357370; called by muse, mutect2, varscan2
- ACSBG2 | c.1977dup p.Q660Tfs*3 | Frame Shift Ins (INS) | VAF 24/114 reads (21%) | catalogued as rs761843213; called by pindel, varscan2
- ACSF2 | c.936C>A p.C312* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99366170; called by muse, mutect2
- ACSL1 | c.916-1G>T p.X306_splice | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99860604; called by muse, mutect2, varscan2
- ACSL3 | c.1152G>A p.P384= | Splice Region (SNP) | VAF 44/124 reads (35%) | catalogued as rs757265756, COSV62481259, COSV62483547; called by muse, mutect2, varscan2
- ACSL5 | c.1243G>A p.V415I (on ENST00000354273; = p.V471I on NM_016234.3) | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs201224468, COSV100634580; called by muse, mutect2, varscan2
- ACSL6 | c.1664G>A p.R555Q (on ENST00000379240; = p.R580Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1489614135, COSV57303962, COSV99734756; called by muse, mutect2, varscan2
- ACSL6 | c.31C>T p.R11* (on ENST00000379240; = p.R36* on NM_015256.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs767774674, COSV57295759; called by muse, mutect2, varscan2
- ACSM1 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99532919; called by muse, varscan2
- ACSM2A | c.1320C>A p.D440E (on ENST00000219054; = p.D361E on NM_001308169.2) | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV99525207; called by muse, mutect2, varscan2
- ACSM3 | c.502G>T p.A168S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.774); catalogued as COSV99184480; called by muse, mutect2, varscan2
- ACSS2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs946609628, COSV53624265; called by muse, mutect2, varscan2
- ACSS3 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs752461783, COSV54101283; called by muse, mutect2, varscan2
- ACTB | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.179); catalogued as COSV100079613; called by muse, mutect2, varscan2
- ACTL7A | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs1350601168, COSV100453101; called by muse, varscan2
- ACTN1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs771989409, COSV99517813; called by muse, mutect2, varscan2
- ACTR2 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV99573884; called by muse, mutect2
- ACTRT1 | c.830A>C p.K277T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.597); catalogued as COSV100947586; called by muse, mutect2, varscan2
- ACTRT3 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs1371242835, COSV100377440; called by muse, mutect2, varscan2
- ACVR1C | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV99694649; called by muse, mutect2, varscan2
- ADA | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 21/122 reads (17%) | catalogued as COSV100866599; called by muse, mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 13/75 reads (17%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAL | c.404A>C p.E135A | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV101052528; called by muse, mutect2, varscan2
- ADAM12 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100900434; called by muse, mutect2, varscan2
- ADAM21 | c.727G>T p.D243Y | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs750187868, COSV99960980; called by muse, mutect2, varscan2
- ADAM28 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99738401; called by muse, mutect2, varscan2
- ADAM29 | c.1896G>T p.K632N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV100822006; called by muse, mutect2, varscan2
- ADAM30 | c.1480C>T p.R494C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as rs149279290; called by muse, mutect2, varscan2
- ADAM30 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101023850; called by muse, mutect2
- ADAM32 | c.1949C>A p.P650H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101165392; called by muse, mutect2, varscan2
- ADAMTS1 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs765139475, COSV99536100; called by muse, mutect2, varscan2
- ADAMTS16 | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV56993327, COSV99941073; called by muse, mutect2
- ADAMTS17 | c.2531C>A p.P844H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99170634; called by muse, mutect2, varscan2
- ADAMTS17 | c.2345T>G p.V782G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV99170637; called by muse, mutect2, varscan2
- ADAMTS20 | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.052); catalogued as COSV101239254; called by muse, mutect2, varscan2
- ADAMTS4 | c.2464G>T p.A822S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100917750; called by muse, mutect2, varscan2
- ADAMTS9 | c.5233C>T p.L1745F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.595); catalogued as COSV99899363; called by muse, mutect2, varscan2
- ADAMTSL1 | c.677-1G>A p.X226_splice | Splice Site (SNP) | VAF 10/106 reads (9%) | catalogued as COSV52820085, COSV99442612; called by muse, mutect2
- ADAMTSL3 | c.773G>A p.R258K | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV54457185; called by muse, mutect2, varscan2
- ADAMTSL4 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99647250; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2566G>T p.A856S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV99647255; called by muse, mutect2, varscan2
- ADAT1 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV100329213; called by muse, mutect2, varscan2
- ADCK2 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99301596; called by muse, varscan2
- ADCY1 | c.2575C>A p.L859I | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as COSV99811930; called by muse, mutect2, varscan2
- ADCY6 | c.2283+1G>A p.X761_splice | Splice Site (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100326608; called by muse, mutect2, varscan2
- ADCY7 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs200651932, COSV54272373; called by muse, varscan2
- ADCY7 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs370653104, COSV99575976; called by muse, varscan2
- ADCY9 | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53582731, COSV99569952; called by muse, mutect2
- ADCY9 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as COSV99569954; called by muse, mutect2, varscan2
- ADD1 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273942; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA3 | c.3341A>G p.K1114R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99293243; called by muse, mutect2, varscan2
- ADGRB1 | c.1802C>A p.A601D | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100029613; called by muse, mutect2, varscan2
- ADGRB3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV65412280; called by muse, mutect2, varscan2
- ADGRB3 | c.2956C>A p.L986I | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99484939; called by muse, mutect2, varscan2
- ADGRE3 | c.1387A>G p.M463V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV99506183; called by muse, mutect2, varscan2
- ADGRE5 | c.1933T>C p.F645L (on ENST00000242786 / NM_078481.4; = p.F552L on NM_001784.5) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.963); catalogued as COSV99660288; called by muse, mutect2
- ADGRF2 | c.1081G>A p.V361I (on ENST00000296862 / NM_001368115.2; = p.V293I on NM_153839.7) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV99731161; called by muse, mutect2, varscan2
- ADGRF5 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as rs776935511, COSV99345545; called by muse, mutect2, varscan2
- ADGRF5 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as COSV99345550; called by muse, mutect2, varscan2
- ADGRG1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.073); catalogued as COSV101113408; called by muse, mutect2
- ADGRG2 | c.3011G>T p.R1004M (on ENST00000379869 / NM_001079858.3; = p.R1001M on NM_005756.4) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100492231; called by muse, mutect2, varscan2
- ADGRG4 | c.2465C>T p.T822I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV99795381; called by muse, varscan2
- ADGRG4 | c.8927C>T p.T2976I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV99795383; called by muse, mutect2, varscan2
- ADGRL2 | c.3818G>A p.R1273Q (on ENST00000370717 / NM_001366005.1; = p.R1217Q on NM_012302.4) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs760725709, COSV99588895; called by muse, mutect2, varscan2
- ADGRL3 | c.2912G>A p.R971Q (on ENST00000506720 / NM_001322402.2; = p.R903Q on NM_015236.6) | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771097660, COSV72230590, COSV72231107; called by muse, mutect2, varscan2
- ADGRL4 | c.325+2T>C p.X109_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | catalogued as COSV100875937; called by muse, mutect2, varscan2
- ADGRL4 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as COSV100875938; called by muse, mutect2
- ADGRV1 | c.15340A>G p.N5114D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV101315874; called by muse, mutect2, varscan2
- ADIPOR1 | c.648T>G p.I216M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV100579512; called by muse, mutect2
- ADIPOR2 | c.925G>T p.G309W | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100840090; called by muse, mutect2, varscan2
- ADNP | c.3166C>T p.R1056C | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs749636302, COSV62426900; called by muse, mutect2, varscan2
- ADNP2 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as COSV100080815; called by muse, mutect2, varscan2
- ADORA3 | c.760T>G p.Y254D | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99598724; called by muse, mutect2, varscan2
- ADRB3 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100799891; called by muse, mutect2
- AEBP1 | c.1601G>A p.R534H | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748807608, COSV56260824; called by muse, mutect2, varscan2
- AEBP1 | c.2039G>A p.G680D | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99788751; called by muse, mutect2, varscan2
- AEBP1 | c.2833A>G p.I945V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV99788752; called by muse, mutect2, varscan2
- AFAP1 | c.2003C>A p.S668Y | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs757007611, COSV100631480, COSV61795722; called by muse, mutect2, varscan2
- AFAP1L1 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.73); PolyPhen probably damaging (0.994); catalogued as COSV99695874; called by muse, mutect2, varscan2
- AFDN | c.2698G>T p.E900* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100652951, COSV100653101; called by muse, mutect2, varscan2
- AFDN | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.772); catalogued as rs754140439, COSV100652953; called by muse, mutect2, varscan2
- AFDN | c.4796C>A p.A1599D | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV100652954; called by muse, mutect2, varscan2
- AFF2 | c.2509C>T p.R837C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs782465333, CM128723, COSV53995030; called by muse, mutect2, varscan2
- AFF2 | c.2572A>C p.I858L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV54004022, COSV99663790; called by muse, mutect2, varscan2
- AFF2 | c.3232G>T p.E1078* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99663797; called by muse, mutect2, varscan2
- AFF3 | c.3049G>A p.A1017T | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417827; called by muse, mutect2
- AFF3 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100418651, COSV100418770; called by muse, mutect2, varscan2
- AGAP3 | c.275T>G p.L92R (on ENST00000622464; = p.L128R on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103808; called by muse, mutect2
- AGBL2 | c.14T>G p.L5W | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV99771637; called by muse, mutect2, varscan2
- AGFG1 | c.595C>A p.L199I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59514722; called by muse, mutect2
- AGL | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs528260114, COSV99649152; called by muse, mutect2, varscan2
- AGO2 | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV55052318; called by muse, mutect2, varscan2
- AGPAT3 | c.234C>A p.D78E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as COSV99377402; called by muse, mutect2, varscan2
- AGR3 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100123953; called by muse, mutect2, varscan2
- AHCTF1 | c.5338C>T p.R1780C (on ENST00000366508; = p.R1754C on NM_015446.5) | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); catalogued as rs374602603; called by muse, mutect2, varscan2
- AHCTF1 | c.4085C>T p.P1362L (on ENST00000366508; = p.P1336L on NM_015446.5) | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774592486, COSV100403630; called by muse, mutect2, varscan2
- AHCTF1 | c.218T>C p.F73S (on ENST00000366508; = p.F47S on NM_015446.5) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV100403633; called by muse, mutect2, varscan2
- AHCYL2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.506); catalogued as rs760655929, COSV100273359; called by muse, mutect2, varscan2
- AHI1 | c.1201C>A p.L401I | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99662663; called by muse, mutect2, varscan2
- AHNAK | c.11938C>T p.P3980S | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99947277; called by muse, mutect2, varscan2
- AHNAK | c.3761T>C p.M1254T | Missense Mutation (SNP) | VAF 83/238 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.956); catalogued as COSV99947278; called by muse, mutect2, varscan2
- AHSG | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs376930727; called by muse, mutect2, varscan2
- AIFM1 | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99781006; called by muse, mutect2, varscan2
- AIFM2 | c.761A>G p.K254R | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100325685; called by muse, mutect2, varscan2
- AK2 | c.395G>A p.R132H (on ENST00000354858; = p.R174H on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs760832831, COSV100709953; called by muse, varscan2
- AKAP1 | c.2299G>A p.A767T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs914781524, COSV100532843; called by muse, mutect2, varscan2
- AKAP11 | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99213888; called by muse, mutect2, varscan2
- AKAP12 | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1263267238, COSV99482131; called by muse, mutect2, varscan2
- AKAP17A | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1487216655, COSV58311966, COSV58312170; called by muse, mutect2, varscan2
- AKAP17A | c.1114T>C p.S372P | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100002203; called by muse, mutect2, varscan2
- AKAP17A | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.043); catalogued as rs149990639, COSV100002206; called by muse, mutect2, varscan2
- AKAP8L | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV101275795; called by muse, mutect2, varscan2
- AKIP1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100214918; called by muse, mutect2, varscan2
- AKT3 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99795304, COSV99796447; called by muse, varscan2
- AL035425.2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100929542; called by muse, mutect2, varscan2
- AL035461.3 | c.2462T>C p.L821S | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101125844; called by muse, mutect2, varscan2
- AL136295.1 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.147); catalogued as rs1043570962, COSV99937987; called by mutect2, varscan2
- AL592490.1 | c.2189T>C p.I730T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101308183; called by muse, mutect2, varscan2
- ALDH16A1 | c.1039del p.A347Lfs*155 | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | catalogued as rs1368010977; called by mutect2, pindel, varscan2
- ALDH18A1 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs773903524, COSV100973155; called by muse, mutect2, varscan2
- ALDH1A3 | c.734C>A p.S245Y | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs766595446, COSV60902228; called by muse, mutect2, varscan2
- ALDH1A3 | c.1478C>A p.A493D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52610132, COSV99439702; called by muse, mutect2
- ALDH1L1 | c.1224C>T p.Y408= | Splice Region (SNP) | VAF 20/53 reads (38%) | catalogued as rs202148769, COSV56417819; called by muse, mutect2, varscan2
- ALDH2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs761154464, COSV55665403, COSV99922935; called by muse, mutect2, varscan2
- ALDH5A1 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs201465237, COSV62373941; called by muse, mutect2, varscan2
- ALDH9A1 | c.271C>A p.Q91K | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1347845234, COSV100699300; called by muse, mutect2, varscan2
- ALG10B | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.213); catalogued as COSV100439891; called by muse, mutect2, varscan2
- ALG5 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 22/46 reads (48%) | catalogued as rs747848311, COSV99523651; called by muse, mutect2, varscan2
- ALG8 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.405); catalogued as COSV100220071, COSV55202449; called by muse, varscan2
- ALG9 | c.520C>G p.L174V | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as rs1050204842, COSV101211889; called by muse, mutect2, varscan2
- ALK | c.4562C>A p.P1521H | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs1318926775, COSV101201935; called by muse, mutect2, varscan2
- ALK | c.1339A>T p.T447S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.149); catalogued as COSV101201936; called by muse, mutect2, varscan2
- ALKBH1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs142904199, COSV99380579; called by muse, mutect2, varscan2
- ALMS1 | c.2873G>T p.S958I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV100042358; called by muse, mutect2
- ALMS1 | c.5798T>C p.I1933T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100042359; called by muse, mutect2, varscan2
- ALOX12B | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as COSV100047066; called by muse, mutect2, varscan2
- ALOX12B | c.999G>T p.K333N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV100047070; called by muse, varscan2
- ALPK2 | c.4858G>T p.D1620Y | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100864291, COSV100864345; called by muse, mutect2, varscan2
- ALPK3 | c.4191C>A p.C1397* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV51939333, COSV99360840; called by muse, mutect2, varscan2
- ALPL | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as CD117837, COSV66376610; called by muse, mutect2, varscan2
- ALS2 | c.4835C>T p.A1612V | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99969258; called by muse, mutect2, varscan2
- AMHR2 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV99143198; called by muse, mutect2, varscan2
- AMOT | c.2525C>T p.S842L (on ENST00000371959 / NM_001113490.1; = p.S433L on NM_133265.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs1406889079, COSV100494995, COSV100495007; called by muse, mutect2, varscan2
- AMOT | c.2184G>T p.Q728H (on ENST00000371959 / NM_001113490.1; = p.Q319H on NM_133265.3) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59063158; called by muse, mutect2, varscan2
- AMPD1 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374697989, COSV62415501; called by muse, mutect2, varscan2
- AMPD3 | c.409G>A p.G137R (on ENST00000396553 / NM_001025389.2; = p.G146R on NM_000480.3) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101158161; called by muse, mutect2, varscan2
- AMPD3 | c.1337G>T p.S446I (on ENST00000396553 / NM_001025389.2; = p.S455I on NM_000480.3) | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV101158162; called by muse, mutect2, varscan2
- AMY2B | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 67/293 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767168411, COSV100796287; called by muse, mutect2, varscan2
- AMZ2 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.71); catalogued as rs782741991, COSV100703152; called by muse, mutect2, varscan2
- ANAPC16 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.959); catalogued as COSV100191899; called by muse, mutect2, varscan2
- ANAPC4 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.057); catalogued as COSV100193986; called by muse, mutect2, varscan2
- ANGPTL7 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs775409689, COSV100816141; called by muse, mutect2, varscan2
- ANK2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 81/207 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV52175026; called by muse, mutect2, varscan2
- ANK3 | c.6970C>T p.P2324S | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99779772; called by muse, mutect2, varscan2
- ANK3 | c.5213C>A p.T1738N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV99779773; called by muse, mutect2, varscan2
- ANKAR | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as rs759825015, COSV99854205; called by muse, mutect2, varscan2
- ANKEF1 | c.2234G>T p.R745M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV101000997, COSV65692300; called by muse, mutect2, varscan2
- ANKFY1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1337405317, COSV58918296; called by muse, mutect2, varscan2
- ANKIB1 | c.722T>G p.I241S | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99728988; called by mutect2, varscan2
- ANKRD11 | c.5606C>T p.P1869L | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1486454956, COSV99969226; called by muse, mutect2
- ANKRD13B | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV101198897; called by muse, mutect2, varscan2
- ANKRD13B | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762020530, COSV100801238; called by muse, mutect2, varscan2
- ANKRD13C | c.407A>C p.N136T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV52036291; called by muse, mutect2, varscan2
- ANKRD20A4P | c.2297G>T p.R766I | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100628529; called by muse, mutect2, varscan2
- ANKRD22 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.966); catalogued as COSV100905472; called by muse, mutect2, varscan2
- ANKRD26 | c.2362C>A p.L788M | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV101063187; called by muse, mutect2, varscan2
- ANKRD28 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV67516849; called by muse, mutect2, varscan2
- ANKRD30A | c.1709G>A p.S570N (on ENST00000611781; = p.S514N on NM_052997.2) | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV100653465; called by muse, mutect2
- ANKRD33 | c.701C>A p.S234Y (on ENST00000340970 / NM_001304459.2; = p.L426M on NM_182608.4) | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV100001285; called by muse, mutect2, varscan2
- ANKRD34A | c.1444C>A p.L482M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100041238; called by muse, mutect2, varscan2
- ANKRD34B | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100103516; called by muse, mutect2, varscan2
- ANKRD35 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100841621, COSV100841722; called by muse, varscan2
- ANKRD39 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as rs754661153, COSV101135623; called by muse, mutect2, varscan2
- ANKRD44 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as COSV99984926; called by muse, mutect2
- ANKRD45 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.859); catalogued as rs1227973549, COSV60961987; called by muse, mutect2, varscan2
- ANKRD46 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs1224254357, COSV100170026; called by muse, mutect2, varscan2
- ANKRD50 | c.2485G>A p.V829M | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101538951; called by muse, mutect2, varscan2
- ANKRD55 | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100591279; called by muse, mutect2, varscan2
- ANKS4B | c.179G>T p.R60M | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100289818; called by muse, mutect2, varscan2
- ANKS6 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs561775954, COSV62051573; called by muse, mutect2, varscan2
- ANKS6 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as rs1306952839, COSV62049044; called by muse, mutect2, varscan2
- ANLN | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99732250; called by muse, mutect2, varscan2
- ANO3 | c.1449C>T p.A483= | Splice Region (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99882660; called by muse, mutect2, varscan2
- ANO3 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760680753, COSV56807795, COSV99882662; called by muse, mutect2, varscan2
- ANO4 | c.926G>A p.R309Q (on ENST00000392977 / NM_001286615.2; = p.R274Q on NM_178826.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs757024624, COSV100152812, COSV100153324; called by mutect2, varscan2
- ANO5 | c.1948A>C p.K650Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as COSV100201821; called by muse, mutect2, varscan2
- ANO5 | c.2469G>A p.M823I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.052); catalogued as COSV100201823; called by muse, mutect2, varscan2
- ANO6 | c.2243A>G p.D748G | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100263118; called by muse, mutect2, varscan2
- ANTXR1 | c.1363G>A p.D455N | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035006322, COSV100362462; called by muse, mutect2, varscan2
- ANXA1 | c.87A>C p.K29N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.581); catalogued as COSV99973919; called by muse, mutect2, varscan2
- ANXA1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1369672677, COSV99973915; called by muse, mutect2, varscan2
- ANXA11 | c.1433G>A p.G478D | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99627110; called by muse, mutect2, varscan2
- ANXA4 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs761374777, COSV101268796; called by muse, mutect2, varscan2
- ANXA5 | c.870G>T p.K290N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.964); catalogued as COSV99634353; called by muse, mutect2, varscan2
- ANXA5 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634355; called by muse, mutect2, varscan2
- ANXA6 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.019); catalogued as rs1433612942, COSV62907764, COSV62909030; called by muse, mutect2, varscan2
- AOC2 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99513631; called by muse, mutect2, varscan2
- AOPEP | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99468323; called by muse, mutect2, varscan2
- AP1AR | c.728A>C p.K243T | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); catalogued as COSV99914169; called by muse, mutect2, varscan2
- AP2A2 | c.852G>T p.E284D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV100172856; called by muse, mutect2, varscan2
- AP2B1 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99251212; called by muse, mutect2, varscan2
- AP3M2 | c.446-2A>G p.X149_splice | Splice Site (SNP) | VAF 36/75 reads (48%) | catalogued as COSV99441543; called by muse, mutect2, varscan2
- AP4B1 | c.1633T>G p.L545V | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.312); catalogued as COSV99870778; called by muse, mutect2, varscan2
- AP4S1 | c.12T>A p.F4L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99364221; called by muse, mutect2, varscan2
- AP5Z1 | c.2315C>T p.T772M | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs745379886, COSV62243363; called by muse, varscan2
- APBA1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as rs766705353, COSV99595628; called by muse, mutect2, varscan2
- APBA3 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1336459269, COSV99516037; called by muse, mutect2, varscan2
- APBB1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs772671906, COSV100193965; called by muse, mutect2, varscan2
- APC | c.1239A>G p.I413M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs899607401, CD005385, COSV99967707; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.6077C>A p.S2026Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57342873; called by muse, mutect2, varscan2
- APLP2 | c.2150G>T p.R717M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99599683; called by muse, varscan2
- APOA4 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as rs145184607; called by muse, mutect2, varscan2
- APOA5 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs757827003, CM151071, COSV99911307; called by muse, varscan2
- APOB | c.10922C>T p.S3641F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV99265512, COSV99268083; called by muse, mutect2, varscan2
- APOH | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV99235747; called by muse, mutect2, varscan2
- APOL6 | c.882G>T p.Q294H | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV101290995; called by muse, mutect2, varscan2
- APP | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100695717; called by muse, mutect2, varscan2
- APPL2 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as rs1314012568, COSV51588026; called by muse, mutect2, varscan2
- AQP8 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99563928; called by muse, mutect2, varscan2
- ARAF | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs62636600, COSV99283168, COSV99283178; called by muse, mutect2, varscan2
- ARAP2 | c.4176G>T p.K1392N | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV100394610; called by muse, mutect2, varscan2
- ARAP2 | c.3186A>C p.R1062S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100394614; called by muse, mutect2, varscan2
- ARAP3 | c.3909-1G>A p.X1303_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99499683; called by muse, mutect2, varscan2
- ARHGAP20 | c.2429C>T p.S810F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs368438533; called by muse, mutect2, varscan2
- ARHGAP20 | c.2315C>A p.A772D | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV99503947, COSV99505675; called by muse, mutect2, varscan2
- ARHGAP21 | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100256172; called by muse, mutect2, varscan2
- ARHGAP21 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV100256175; called by muse, mutect2, varscan2
- ARHGAP22 | c.2024G>T p.R675M | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV99985180; called by muse, mutect2, varscan2
- ARHGAP22 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs755161585, COSV99985184; called by muse, varscan2
- ARHGAP24 | c.1859G>T p.S620I (on ENST00000395184 / NM_001025616.3; = p.S527I on NM_031305.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV99982053; called by muse, mutect2, varscan2
- ARHGAP26 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99190910; called by muse, mutect2
- ARHGAP28 | c.694G>A p.G232R (on ENST00000383472 / NM_001366230.1; = p.G73R on NM_001010000.3) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV51647555; called by muse, mutect2, varscan2
- ARHGAP30 | c.2340G>T p.E780D | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.111); catalogued as COSV100920251; called by muse, mutect2, varscan2
- ARHGAP31 | c.1111G>T p.G371C | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV51789850, COSV99956657; called by muse, varscan2
- ARHGAP31 | c.4063C>A p.P1355T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99957075; called by muse, mutect2, varscan2
- ARHGAP36 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs1260194575, COSV99357649; called by muse, mutect2, varscan2
- ARHGAP4 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100604029; called by muse, varscan2
- ARHGAP4 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs782680206, COSV100604030; called by muse, mutect2, varscan2
- ARHGAP9 | c.1813T>C p.Y605H (on ENST00000393797 / NM_001319850.2; = p.Y586H on NM_032496.4) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99954095; called by muse, mutect2, varscan2
- ARHGEF12 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV100754889; called by muse, mutect2, varscan2
- ARHGEF18 | c.1702G>A p.A568T (on ENST00000359920 / NM_001130955.2; = p.A464T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs201212270, COSV100149338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF18 | c.3148C>T p.P1050S (on ENST00000359920 / NM_001130955.2; = p.P946S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60469074; called by muse, mutect2, varscan2
- ARHGEF26 | c.1799C>A p.S600Y | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726544; called by muse, mutect2, varscan2
- ARHGEF28 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV99708994; called by muse, mutect2, varscan2
- ARHGEF37 | c.894G>T p.Q298H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100382098; called by muse, mutect2, varscan2
- ARHGEF6 | c.1308T>G p.I436M | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99166452; called by muse, mutect2, varscan2
- ARID1A | c.1650dup p.Y551Lfs*72 | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | catalogued as rs1415146710; called by mutect2, pindel, varscan2
- ARID3B | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs145901163; called by muse, mutect2, varscan2
- ARID4B | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753915756, COSV51597949, COSV51602687; called by muse, mutect2, varscan2
- ARID5B | c.3266C>T p.S1089L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs1170860237, COSV54414711; called by muse, mutect2, varscan2
- ARIH2 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs1021548669, COSV100711304; called by muse, mutect2, varscan2
- ARL11 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV56291029, COSV99949078; called by muse, varscan2
- ARL14 | c.172C>T p.L58F | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs17853289, COSV57900708; called by muse, mutect2, varscan2
- ARL3 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV99589040; called by muse, varscan2
- ARL6IP5 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 88/242 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774792987, COSV56235683, COSV99833029; called by muse, mutect2, varscan2
- ARMC2 | c.2378C>T p.T793I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1203160926, COSV100933545; called by muse, mutect2, varscan2
- ARMC3 | c.1929-1G>T p.X643_splice | Splice Site (SNP) | VAF 19/74 reads (26%) | catalogued as COSV99958023; called by muse, mutect2, varscan2
- ARMC4 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99518565; called by muse, mutect2, varscan2
- ARMH3 | c.1729G>T p.G577C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV100898922; called by muse, mutect2, varscan2
- ARPC2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs200038830, COSV55286220; called by muse, mutect2, varscan2
- ARPC2 | c.586C>T p.P196S | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99826691; called by muse, mutect2, varscan2
- ARPIN | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV100673451; called by muse, mutect2, varscan2
- ARPP21 | c.293C>A p.S98Y | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV51792463, COSV99491948; called by muse, mutect2, varscan2
- ARPP21 | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV99491951; called by muse, mutect2, varscan2
- ARRB2 | c.1083C>T p.A361= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as rs376581927; called by muse, varscan2
- ARRDC2 | c.287C>A p.T96N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.073); catalogued as COSV99716741; called by muse, mutect2, varscan2
- ARRDC5 | c.454T>G p.L152V (on ENST00000381781; = p.L138V on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV101108159; called by muse, mutect2, varscan2
- ASAP3 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1240975876, COSV100369419; called by muse, mutect2, varscan2
- ASB12 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs752937556, COSV100744703; called by muse, mutect2, varscan2
- ASCC3 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100225682; called by muse, mutect2, varscan2
- ASH2L | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.44); catalogued as rs762664012, COSV51700338; called by muse, mutect2, varscan2
- ASH2L | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99166969; called by muse, mutect2, varscan2
- ASIC5 | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101539740; called by muse, mutect2, varscan2
- ASNS | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs149193118; called by muse, mutect2, varscan2
- ASPA | c.395G>T p.R132M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.245); catalogued as COSV99559216; called by mutect2, varscan2
- ASPH | c.599A>G p.E200G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); catalogued as COSV100727541; called by muse, varscan2
- ASPM | c.5993T>G p.L1998R | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.214); catalogued as COSV99660319; called by muse, mutect2, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by muse, mutect2, varscan2
- ASPM | c.1746A>C p.E582D | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99660320; called by muse, mutect2, varscan2
- ASPM | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99660321; called by muse, mutect2, varscan2
- ASXL2 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711036; called by muse, mutect2, varscan2
- ASXL3 | c.5474A>T p.N1825I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV99324789; called by muse, mutect2, varscan2
- ASXL3 | c.5591G>A p.G1864D | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.073); catalogued as COSV99324790; called by muse, mutect2, varscan2
- ATAD2 | c.1171A>C p.N391H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752748660, COSV54883270; called by muse, mutect2, varscan2
- ATAD5 | c.1344A>C p.E448D | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV100429934; called by muse, mutect2, varscan2
- ATAD5 | c.3797C>A p.S1266Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV100429935; called by muse, mutect2, varscan2
- ATF6B | c.1863G>A p.M621I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100916820; called by muse, mutect2, varscan2
- ATF6B | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100913563; called by mutect2, varscan2
- ATF7IP2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV100202611; called by muse, mutect2, varscan2
- ATG14 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99902765; called by muse, mutect2, varscan2
- ATG16L1 | c.1619T>C p.V540A (on ENST00000392017 / NM_030803.7; = p.V521A on NM_017974.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.99); PolyPhen benign (0.012); catalogued as COSV100731311; called by muse, varscan2
- ATG2B | c.5459G>A p.R1820Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as rs760536921, COSV99952041; called by muse, mutect2, varscan2
- ATG4C | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 39/123 reads (32%) | catalogued as COSV100508092; called by muse, mutect2, varscan2
- ATG4D | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100521014; called by muse, mutect2, varscan2
- ATG9A | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100772579; called by muse, varscan2
- ATL2 | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as COSV100184616; called by muse, mutect2, varscan2
- ATL3 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.397); catalogued as COSV60296506; called by muse, mutect2, varscan2
- ATM | c.4973C>T p.A1658V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99589522; called by muse, mutect2, varscan2
- ATP10A | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV100791201; called by muse, mutect2, varscan2
- ATP11C | c.3095C>A p.S1032Y | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100557861; called by muse, mutect2, varscan2
- ATP11C | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV59564605; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs35191129; called by mutect2, pindel, varscan2
- ATP13A3 | c.2457G>T p.E819D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.023); catalogued as rs969115185, COSV55461229, COSV99756977; called by muse, mutect2, varscan2
- ATP1A1 | c.1588C>A p.L530M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.178); catalogued as COSV99814416; called by muse, mutect2, varscan2
- ATP1A2 | c.2458G>A p.A820T | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100767822; called by muse, mutect2, varscan2
- ATP1A3 | c.2404C>A p.P802T (on ENST00000545399 / NM_001256214.2; = p.P789T on NM_152296.5) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100132235; called by muse, mutect2, varscan2
- ATP1A3 | c.1829G>A p.R610H (on ENST00000545399 / NM_001256214.2; = p.R597H on NM_152296.5) | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100132236; called by muse, mutect2, varscan2
- ATP1A3 | c.1162C>T p.R388C (on ENST00000545399 / NM_001256214.2; = p.R375C on NM_152296.5) | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1057524683, COSV57488873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1A4 | c.74T>G p.L25R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100927533; called by muse, varscan2
- ATP1A4 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV100927534; called by muse, varscan2
- ATP2A1 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750049229, COSV63922116; called by muse, mutect2, varscan2
- ATP2A3 | c.2447T>A p.I816N | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99989114; called by muse, mutect2, varscan2
- ATP2B1 | c.3301C>T p.R1101W | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs746094247, COSV53807246; called by muse, mutect2, varscan2
- ATP2B1 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV99665639; called by muse, mutect2, varscan2
- ATP2C1 | c.2106C>A p.F702L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100146663, COSV60754905; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1787G>A p.C596Y | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100377004; called by muse, mutect2, varscan2
- ATP6V0A2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs752522705, COSV100377006, COSV57752412; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs201691017, COSV101214977; called by muse, mutect2, varscan2
- ATP7A | c.3570A>T p.R1190S | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100430746; called by muse, mutect2, varscan2
- ATR | c.5203C>A p.H1735N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100638196; called by muse, mutect2, varscan2
- ATR | c.59+1G>A p.X20_splice | Splice Site (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100638198; called by muse, mutect2, varscan2
- ATRX | c.7220G>A p.R2407Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs1557034949, COSV64880601; called by muse, mutect2, varscan2
- ATRX | c.6067C>A p.L2023I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100970694; called by muse, mutect2, varscan2
- ATRX | c.5251C>T p.L1751F | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100970695; called by muse, mutect2
- ATRX | c.3597C>G p.D1199E | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs1374906936, COSV100970699, COSV64881973; called by muse, mutect2
- ATRX | c.2356T>C p.S786P | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100970703; called by muse, mutect2, varscan2
- ATXN2L | c.920C>A p.P307H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100294265; called by muse, mutect2, varscan2
- ATXN3L | c.329G>T p.R110I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV101019339; called by muse, mutect2, varscan2
- AURKC | c.563C>A p.S188Y (on ENST00000302804 / NM_001015878.2; = p.S154Y on NM_003160.3) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100248844, COSV57136931; called by muse, mutect2, varscan2
- AXIN2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202108391, COSV100196456; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GLCT | c.1448A>T p.E483V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV100587286; called by muse, mutect2
- B3GNT4 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.799); catalogued as rs140214004; called by muse, mutect2
- B3GNT6 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV100845783; called by muse, mutect2
- B4GALT3 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157726; called by muse, mutect2, varscan2
- B9D1 | c.600G>T p.Q200H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99264942; called by muse, mutect2
- BACE1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100475017; called by mutect2, varscan2
- BACH2 | c.1405G>T p.G469* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99999297; called by muse, mutect2
- BAG3 | c.1447G>A p.G483S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs570294713, COSV100958228; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- BAHCC1 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as COSV100311607; called by muse, mutect2
- BAHCC1 | c.6293C>A p.A2098D | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV100311609; called by muse, mutect2, varscan2
- BAIAP2 | c.1269G>C p.M423I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV100348063; called by muse, varscan2
- BAIAP2 | c.1636G>A p.A546T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs544323535, COSV100352782; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs751577726, COSV99133819; called by muse, mutect2, varscan2
- BAIAP3 | c.1006G>T p.G336* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV100181442; called by muse, mutect2, varscan2
- BAK1 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.105); catalogued as rs372889857; called by muse, varscan2
- BAMBI | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.476); catalogued as rs370815245, COSV100977500; called by muse, mutect2, varscan2
- BANK1 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100536304; called by muse, mutect2, varscan2
- BANK1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs769575241, COSV100536307; called by muse, mutect2, varscan2
- BARD1 | c.1319A>G p.D440G | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753446928, COSV53609052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAZ2B | c.5740C>A p.L1914M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.622); catalogued as COSV100600618; called by muse, mutect2, varscan2
- BAZ2B | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.028); catalogued as COSV100600620; called by muse, mutect2, varscan2
- BBS10 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs553291328, CM111656, COSV99674826; called by muse, varscan2
- BBS12 | c.1007C>A p.T336N | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100044812, COSV100044931; called by muse, mutect2, varscan2
- BBS7 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99144909; called by muse, mutect2
- BBS7 | c.1371+1G>T p.X457_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99144910; called by muse, mutect2, varscan2
- BCDIN3D | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs764721935, COSV61702743; called by muse, mutect2, varscan2
- BCL6 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as rs1246753673, COSV99215663; called by muse, mutect2, varscan2
- BCL6 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 21/78 reads (27%) | catalogued as COSV51655220, COSV99215666; called by muse, mutect2, varscan2
- BCL6B | c.1163C>T p.T388M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs769200715, COSV53428344; called by muse, mutect2, varscan2
- BCL9 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782661402, COSV52347257; called by muse, mutect2, varscan2
- BCLAF1 | c.2426G>T p.R809I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV50360551, COSV99219543; called by muse, mutect2, varscan2
- BCLAF3 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 76/215 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100503293, COSV100503422; called by muse, mutect2, varscan2
- BCO1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs747676129, COSV50729947; called by muse, varscan2
- BCOR | c.3493G>T p.V1165F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV100653281; called by muse, varscan2
- BCOR | c.1438A>G p.S480G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100653284; called by muse, varscan2
- BCOR | c.1361A>C p.K454T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100653287; called by muse, varscan2
- BCORL1 | c.3995G>A p.R1332Q | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005100760, COSV54404511; called by muse, mutect2, varscan2
- BCORL1 | c.4879G>A p.D1627N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs367941726, COSV54391920; called by muse, mutect2, varscan2
- BDKRB1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs757505732, COSV99387865; called by muse, mutect2, varscan2
- BDP1 | c.647T>A p.V216D | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV100703040; called by muse, mutect2, varscan2
- BDP1 | c.6982A>G p.R2328G | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs755130824, COSV100703044; called by muse, mutect2, varscan2
- BEND2 | c.1867A>C p.M623L | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV101191991; called by muse, mutect2, varscan2
- BEND2 | c.1130C>T p.T377M | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs28496595, COSV101191993; called by muse, mutect2, varscan2
- BEND5 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1415597483, COSV65718585; called by muse, mutect2, varscan2
- BEST2 | c.97T>C p.W33R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs775071591, COSV99244392; called by muse, varscan2
- BEST3 | c.714G>A p.Q238= | Splice Region (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100437748; called by muse, mutect2
- BFAR | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99902200; called by muse, mutect2, varscan2
- BFSP1 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100925365, COSV64902043; called by muse, mutect2, varscan2
- BHLHE40 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1453596582, COSV99848118; called by muse, varscan2
- BHLHE40 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768340263, COSV99848124; called by muse, varscan2
- BICC1 | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100874845; called by muse, mutect2, varscan2
- BIRC6 | c.3953G>A p.R1318Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs778986518, COSV101428262; called by muse, mutect2, varscan2
- BIRC6 | c.6007A>C p.K2003Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.642); catalogued as COSV101428263; called by muse, mutect2, varscan2
- BIRC6 | c.7663G>A p.G2555R | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs548738385, COSV70202323; called by muse, mutect2, varscan2
- BIRC6 | c.11822G>A p.R3941K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.437); catalogued as COSV101428267; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4337G>A p.R1446Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs377390651, COSV63246081; called by muse, mutect2, varscan2
- BLM | c.2679T>G p.I893M | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100757208; called by muse, mutect2, varscan2
- BMP1 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV100109504; called by muse, mutect2, varscan2
- BMP2K | c.298-1G>T p.X100_splice | Splice Site (SNP) | VAF 27/87 reads (31%) | catalogued as COSV100621704; called by muse, mutect2, varscan2
- BMP3 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99261642; called by muse, mutect2, varscan2
- BMP7 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV101215934; called by muse, mutect2, varscan2
- BMS1 | c.3378G>A p.W1126* | Nonsense Mutation (SNP) | VAF 63/173 reads (36%) | catalogued as rs1428738256, COSV100996697; called by muse, mutect2, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 8/95 reads (8%) | catalogued as COSV51775023; called by muse, mutect2
- BNC2 | c.2528A>C p.K843T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101033139; called by muse, mutect2, varscan2
- BNC2 | c.1176T>G p.N392K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.109); catalogued as COSV101033140; called by muse, mutect2, varscan2
- BOD1L1 | c.7708T>C p.C2570R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV99239283; called by muse, mutect2, varscan2
- BOD1L1 | c.7121C>T p.P2374L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99239286; called by muse, mutect2, varscan2
- BOD1L1 | c.5010C>A p.D1670E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV99239289; called by mutect2, varscan2
- BPNT2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99389014; called by muse, mutect2, varscan2
- BRAF | c.2360C>A p.A787D (on ENST00000288602 / NM_001374244.1; = p.A747D on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as COSV56411766; called by muse, mutect2, varscan2
- BRAT1 | c.1478T>C p.L493P | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100500471; called by muse, mutect2, varscan2
- BRCA2 | c.58A>G p.N20D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV100563927; called by muse, varscan2
- BRCA2 | c.1157A>C p.E386A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as COSV101204195; called by muse, mutect2, varscan2
- BRCA2 | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV101204196; called by muse, mutect2, varscan2
- BRCA2 | c.3364G>T p.G1122* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV101204198, COSV66450396; called by mutect2, varscan2
- BRCC3 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.857); catalogued as COSV100341589, COSV57462296; called by muse, mutect2, varscan2
- BRD7 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99575978; called by muse, mutect2, varscan2
- BRDT | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV100746349; called by muse, mutect2, varscan2
- BRDT | c.1064A>G p.D355G | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100746352; called by muse, varscan2
- BRF1 | c.569T>G p.F190C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527291; called by muse, mutect2, varscan2
- BRINP1 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV56300442; called by muse, mutect2, varscan2
- BRINP1 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs147594978; called by muse, varscan2
- BRMS1 | c.84A>C p.E28D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100240235; called by muse, mutect2, varscan2
- BROX | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV61798868; called by muse, mutect2, varscan2
- BRSK1 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV100510554; called by muse, mutect2, varscan2
- BRSK1 | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 59/174 reads (34%) | catalogued as COSV100474041; called by muse, mutect2, varscan2
- BRWD1 | c.4583C>T p.S1528F | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100312607, COSV100313374; called by muse, mutect2, varscan2
- BRWD1 | c.1211G>T p.S404I | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100313380, COSV100313806; called by muse, mutect2, varscan2
- BRWD3 | c.4762G>A p.E1588K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100956000; called by muse, mutect2, varscan2
- BRWD3 | c.4081-1G>T p.X1361_splice | Splice Site (SNP) | VAF 16/128 reads (13%) | catalogued as COSV100956001; called by muse, mutect2, varscan2
- BRWD3 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV64746018; called by muse, mutect2, varscan2
- BRWD3 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100956003; called by muse, mutect2, varscan2
- BSCL2 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs771322168, COSV54018505; called by muse, mutect2, varscan2
- BSN | c.6697A>G p.I2233V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99608354; called by muse, mutect2, varscan2
- BTAF1 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758296724, COSV99795309; called by muse, mutect2, varscan2
- BTBD6 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as COSV59272282; called by muse, mutect2, varscan2
- BTBD7 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100108024; called by muse, mutect2, varscan2
- BTBD8 | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV100730266; called by muse, mutect2, varscan2
- BTD | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs780655352, COSV100329564; called by muse, mutect2, varscan2
- BTN1A1 | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.59); catalogued as rs765523860, COSV55068781; called by muse, mutect2, varscan2
- BTN2A2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 70/203 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs781579797, COSV100760381; called by muse, varscan2
- BTN3A1 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99175793; called by muse, varscan2
- BTRC | c.219G>T p.K73N (on ENST00000370187 / NM_033637.4; = p.K37N on NM_003939.5) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.775); catalogued as COSV100926548; called by muse, mutect2, varscan2
- BYSL | c.1213C>T p.L405F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100026790; called by muse, mutect2
- C10orf82 | c.374G>T p.R125I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100980095, COSV65024715; called by muse, mutect2, varscan2
- C10orf88 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.787); catalogued as COSV100925017; called by muse, varscan2
- C10orf90 | c.1754C>A p.S585Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52958706; called by muse, mutect2, varscan2
- C11orf54 | c.787C>T p.R263* (on ENST00000331239; = p.R213* on NM_014039.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as rs149785915; called by muse, mutect2, varscan2
- C11orf68 | c.563C>T p.A188V (on ENST00000530188; = p.A229V on NM_031450.4) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.347); catalogued as rs751284287, COSV100437092; called by muse, varscan2
- C11orf94 | c.100A>C p.R34= | Splice Region (SNP) | VAF 33/83 reads (40%) | catalogued as COSV99571423; called by muse, mutect2, varscan2
- C12orf29 | c.598A>G p.N200D | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV100468658; called by muse, mutect2, varscan2
- C12orf29 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1372893314, COSV58351578; called by muse, mutect2, varscan2
- C12orf66 | c.1051T>C p.S351P | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100320715; called by muse, mutect2, varscan2
- C14orf39 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs923790535, COSV100407586; called by muse, mutect2, varscan2
- C15orf39 | c.2596C>A p.L866M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100641330; called by muse, mutect2, varscan2
- C15orf48 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs143173357, COSV60223381; called by muse, mutect2, varscan2
- C16orf46 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.36); catalogued as COSV100215296, COSV55150884; called by muse, mutect2, varscan2
- C1QB | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100152754; called by muse, mutect2, varscan2
- C1QTNF1 | c.250T>C p.Y84H | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100189924; called by muse, mutect2, varscan2
- C1R | c.1949A>G p.N650S (on ENST00000536053 / NM_001354346.2; = p.N636S on NM_001733.7) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV101605616; called by muse, mutect2, varscan2
- C1RL | c.1147G>A p.G383S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.489); catalogued as rs765549175, COSV99864672; called by mutect2, varscan2
- C1orf116 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.086); catalogued as COSV100847929, COSV63943820; called by muse, mutect2, varscan2
- C1orf127 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.552); catalogued as rs1490734253, COSV100983479; called by muse, mutect2, varscan2
- C20orf144 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs761579956, COSV99864740; called by muse, varscan2
- C2CD2L | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs761879735, COSV60883769; called by muse, varscan2
- C2CD5 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV61723360; called by muse, mutect2, varscan2
- C2orf78 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as rs1031110023, COSV101280961; called by muse, mutect2, varscan2
- C3 | c.4703C>T p.T1568I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV99836585; called by muse, mutect2, varscan2
- C3 | c.4568C>T p.S1523L | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs765147079, COSV99836587; called by muse, mutect2, varscan2
- C3 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99836595; called by muse, mutect2, varscan2
- C3AR1 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50817489; called by muse, mutect2, varscan2
- C3AR1 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.454); catalogued as COSV99368500; called by muse, mutect2, varscan2
- C3orf20 | c.2168G>T p.S723I | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.246); catalogued as COSV99513853; called by muse, mutect2, varscan2
- C4BPA | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100891209; called by muse, mutect2, varscan2
- C4orf33 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99828904; called by muse, varscan2
- C5 | c.3677G>A p.R1226H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs756426099, COSV99797797; called by muse, mutect2, varscan2
- C5 | c.2858T>G p.I953S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as COSV99797799; called by muse, mutect2, varscan2
- C5orf34 | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as COSV100175449; called by muse, mutect2
- C6orf118 | c.481G>T p.G161* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100024476; called by muse, mutect2, varscan2
- C7orf26 | c.892C>A p.L298I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as COSV100732899; called by muse, mutect2, varscan2
- C7orf33 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.676); catalogued as COSV100188785, COSV61022811; called by muse, mutect2, varscan2
- C8orf58 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99254567; called by muse, mutect2, varscan2
- CA13 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58798813; called by muse, mutect2, varscan2
- CA13 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100410162; called by muse, mutect2
- CA5A | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.812); catalogued as rs370816330; called by muse, varscan2
- CA5A | c.388C>T p.H130Y | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59242296; called by muse, mutect2, varscan2
- CA9 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.682); catalogued as rs760622510, COSV100999814; called by muse, varscan2
- CA9 | c.820G>A p.V274M | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65675762; called by muse, varscan2
- CABIN1 | c.2414G>T p.S805I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.853); catalogued as COSV99573158; called by muse, mutect2, varscan2
- CABLES1 | c.1060C>A p.L354M (on ENST00000256925 / NM_001100619.2; = p.L89M on NM_138375.2) | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99908606; called by muse, mutect2, varscan2
- CABP7 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs762471805, COSV53362629; called by muse, mutect2, varscan2
- CACHD1 | c.1534G>A p.D512N | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs760671656, COSV99262199; called by muse, varscan2
- CACHD1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1235538167, COSV51557130, COSV51562484; called by muse, mutect2, varscan2
- CACHD1 | c.3791C>T p.A1264V | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.042); catalogued as COSV51548544; called by muse, mutect2, varscan2
- CACNA1A | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.12); catalogued as COSV100802365; called by muse, mutect2, varscan2
- CACNA1B | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99497211; called by muse, mutect2, varscan2
- CACNA1B | c.5822C>A p.T1941N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV99497215; called by muse, mutect2
- CACNA1C | c.1821G>T p.E607D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100218504; called by muse, mutect2, varscan2
- CACNA1C | c.4854C>A p.F1618L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100218509; called by muse, mutect2, varscan2
- CACNA1F | c.4096T>C p.F1366L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100544759; called by muse, mutect2, varscan2
- CACNA1F | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100544760; called by muse, mutect2, varscan2
- CACNA1I | c.5656G>A p.D1886N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100360181; called by muse, mutect2, varscan2
- CACNA1S | c.3231G>T p.K1077N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763299733, COSV100754971, COSV62937030; called by muse, mutect2, varscan2
- CACNA1S | c.2812C>A p.L938I | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV100754972; called by muse, varscan2
- CACNA2D1 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.201); catalogued as COSV100666595; called by mutect2, varscan2
- CACNA2D4 | c.1805C>A p.S602Y | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.127); catalogued as rs550298852, COSV54954918; called by muse, mutect2, varscan2
- CACNB3 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1283578475; called by muse, mutect2
- CACNG7 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV55813346, COSV55816386; called by muse, mutect2, varscan2
- CAD | c.3154T>A p.S1052T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53029320, COSV99254988; called by muse, mutect2, varscan2
- CADM2 | c.535C>T p.R179C (on ENST00000407528 / NM_001167674.2; = p.R181C on NM_153184.4) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs759648918, COSV101059551, COSV67359574; called by muse, mutect2, varscan2
- CADPS | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99337981; called by muse, mutect2, varscan2
- CALCOCO2 | c.180+1G>T p.X60_splice | Splice Site (SNP) | VAF 24/78 reads (31%) | catalogued as COSV99363774; called by muse, mutect2, varscan2
- CALCR | c.799G>A p.A267T (on ENST00000649521 / NM_001164737.2; = p.A251T on NM_001742.4) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV100810523; called by muse, mutect2, varscan2
- CALR | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs750961102, COSV100330677; called by muse, mutect2, varscan2
- CALU | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs139447748; called by mutect2, varscan2
- CAMK2G | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99989776; called by muse, mutect2
- CAMK4 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99999088; called by mutect2, varscan2
- CAMSAP1 | c.3196G>T p.D1066Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100409819; called by muse, mutect2, varscan2
- CAMSAP3 | c.1876G>A p.A626T | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.181); catalogued as rs535764762, COSV50377055; called by muse, varscan2
- CAMTA1 | c.3327C>A p.F1109L | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100349173; called by muse, mutect2, varscan2
- CANX | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99910423; called by muse, mutect2, varscan2
- CAPN1 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs376981701; called by muse, mutect2, varscan2
- CAPN6 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.786); catalogued as COSV100136859; called by muse, mutect2, varscan2
- CAPN7 | c.870C>A p.C290* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV99512760; called by muse, mutect2, varscan2
- CAPN9 | c.1025A>T p.E342V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.367); catalogued as COSV99680351; called by muse, mutect2, varscan2
- CAPNS1 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1484620249, COSV99497068; called by muse, mutect2, varscan2
- CAPRIN2 | c.1970C>A p.T657N | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV99195493; called by muse, mutect2, varscan2
- CAPRIN2 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.6); catalogued as COSV99195494; called by muse, mutect2, varscan2
- CARD6 | c.2641G>A p.A881T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as rs568433433, COSV99620775; called by muse, mutect2, varscan2
- CARMIL1 | c.2371C>T p.P791S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100277719; called by muse, mutect2, varscan2
- CARMIL1 | c.2502T>G p.I834M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100277723; called by muse, mutect2, varscan2
- CARNS1 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV57053718; called by muse, mutect2, varscan2
- CARS1 | c.1795C>T p.R599W | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1438541322, COSV99542665; called by muse, mutect2, varscan2
- CARS1 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99542669; called by muse, mutect2, varscan2
- CASP7 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100614877; called by muse, mutect2, varscan2
- CASP8AP2 | c.3902C>T p.T1301I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99387032; called by muse, mutect2
- CASP9 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as COSV100423773; called by muse, mutect2, varscan2
- CASP9 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs748271106, COSV100423775; called by muse, mutect2, varscan2
- CASZ1 | c.3901C>T p.H1301Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1165804073, COSV100681301; called by muse, mutect2, varscan2
- CASZ1 | c.3116G>A p.G1039D | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV100681305; called by muse, mutect2
- CATSPER1 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759530121, COSV56410558; called by muse, mutect2, varscan2
- CATSPER4 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100128368, COSV58793094; called by muse, varscan2
- CATSPERB | c.3173C>T p.T1058M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.862); catalogued as rs750984485, COSV99831234; called by muse, mutect2, varscan2
- CATSPERB | c.1042T>G p.F348V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99831236; called by muse, mutect2, varscan2
- CATSPERE | c.998G>A p.R333K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100835141; called by muse, mutect2, varscan2
- CATSPERE | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100835142; called by muse, mutect2, varscan2
- CAVIN3 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV100392485; called by muse, mutect2
- CBLB | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV99913396; called by muse, mutect2, varscan2
- CBLC | c.1285-1G>T p.X429_splice | Splice Site (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99542041; called by muse, mutect2, varscan2
- CBWD1 | c.836T>C p.F279S | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs1445737554; called by mutect2, varscan2
- CBX4 | c.114-2A>G p.X38_splice | Splice Site (SNP) | VAF 21/97 reads (22%) | catalogued as COSV99490330; called by muse, mutect2, varscan2
- CBX5 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99267623; called by muse, mutect2, varscan2
- CBX8 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as rs746334191, COSV99485860; called by muse, varscan2
- CC2D1B | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs373271493, COSV99429959; called by muse, mutect2, varscan2
- CC2D2A | c.3901A>G p.T1301A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101052767; called by muse, mutect2, varscan2
- CCAR1 | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen possibly damaging (0.543); catalogued as COSV99771012; called by muse, mutect2, varscan2
- CCAR2 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1011317024, COSV57907194; called by muse, mutect2, varscan2
- CCAR2 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.536); catalogued as COSV99374011; called by muse, mutect2, varscan2
- CCDC102B | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100103416; called by muse, mutect2, varscan2
- CCDC112 | c.7A>C p.K3Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV101100443; called by muse, mutect2, varscan2
- CCDC120 | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.758); catalogued as COSV100900627; called by muse, mutect2, varscan2
- CCDC127 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745992846, COSV57257855; called by muse, mutect2, varscan2
- CCDC127 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1332870264, COSV57258000; called by muse, mutect2, varscan2
- CCDC136 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1267890226, COSV99922580; called by muse, mutect2, varscan2
- CCDC136 | c.2748G>T p.Q916H | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99922587; called by muse, mutect2, varscan2
- CCDC141 | c.2074A>C p.K692Q | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV99836787; called by muse, mutect2, varscan2
- CCDC146 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99592565; called by muse, mutect2, varscan2
- CCDC15 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as COSV61081425; called by muse, mutect2, varscan2
- CCDC157 | c.389T>C p.L130P | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100600264; called by muse, mutect2, varscan2
- CCDC17 | c.1781G>A p.R594H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs147247705, COSV100601550; called by mutect2, varscan2
- CCDC170 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.364); catalogued as COSV99498403; called by muse, mutect2, varscan2
- CCDC173 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.396); catalogued as COSV101470197; called by muse, mutect2, varscan2
- CCDC18 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV100159543; called by muse, mutect2, varscan2
- CCDC186 | c.2097G>T p.Q699H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as COSV100991109; called by muse, varscan2
- CCDC186 | c.1144A>G p.K382E | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100991110; called by muse, mutect2, varscan2
- CCDC189 | c.392G>A p.C131Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100079559; called by muse, mutect2
- CCDC30 | c.1924G>T p.E642* (on ENST00000340612; = p.E599* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 39/131 reads (30%) | catalogued as COSV100501306; called by muse, mutect2, varscan2
- CCDC39 | c.2656T>C p.S886P | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as COSV99867123; called by muse, mutect2, varscan2
- CCDC39 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 39/101 reads (39%) | catalogued as CM110031, COSV56478346, COSV56481605; called by muse, mutect2, varscan2
- CCDC40 | c.3223C>A p.L1075M | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100163191; called by muse, mutect2, varscan2
- CCDC59 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs921119943, COSV99810664; called by muse, mutect2, varscan2
- CCDC6 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs368599035; called by muse, mutect2, varscan2
- CCDC7 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 6/58 reads (10%) | catalogued as COSV99511577; called by muse, mutect2
- CCDC7 | c.3215G>A p.R1072K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV100178241; called by muse, mutect2, varscan2
- CCDC71 | c.476T>C p.V159A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as COSV100422356; called by muse, mutect2, varscan2
- CCDC73 | c.2014del p.S672Vfs*22 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as rs747131147; called by mutect2, varscan2
- CCDC86 | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV99920127; called by muse, mutect2
- CCDC87 | c.2163G>A p.W721* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs1248786423, COSV100039963; called by muse, mutect2, varscan2
- CCDC88A | c.3973C>T p.R1325W | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1478936546, COSV55059641; called by muse, mutect2, varscan2
- CCDC88B | c.2674C>T p.Q892* | Nonsense Mutation (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100105381; called by muse, mutect2, varscan2
- CCDC88B | c.4157A>T p.E1386V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV99590021; called by muse, mutect2
- CCDC9 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539655267, COSV55721311; called by muse, mutect2, varscan2
- CCDC93 | c.1350+2T>C p.X450_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as rs749076220, COSV100098720; called by muse, mutect2, varscan2
- CCKBR | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100582928; called by muse, mutect2, varscan2
- CCL1 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.072); catalogued as rs760282277, COSV99861733; called by muse, mutect2, varscan2
- CCL19 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs199848815; called by muse, mutect2, varscan2
- CCN4 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.253); catalogued as COSV99137059; called by muse, mutect2
- CCNA1 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 26/91 reads (29%) | catalogued as rs373856311; called by muse, mutect2, varscan2
- CCNB1IP1 | c.827G>T p.R276I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as COSV62302535; called by muse, mutect2, varscan2
- CCNB3 | c.2546G>T p.S849I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99328362, COSV99328995; called by muse, mutect2, varscan2
- CCNB3 | c.3793C>A p.L1265M | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99328996; called by muse, mutect2, varscan2
- CCNE1 | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs776712074, COSV52904484; called by muse, varscan2
- CCNE1 | c.1048A>G p.R350G | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as rs1056559593, COSV52905420, COSV99388380; called by muse, mutect2, varscan2
- CCNH | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs145378845; called by muse, mutect2, varscan2
- CCNI2 | c.666C>A p.H222Q | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.089); catalogued as COSV101107803; called by muse, mutect2, varscan2
- CCNJL | c.514A>G p.K172E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV99979467; called by muse, mutect2, varscan2
- CCNL1 | c.1148G>A p.S383N | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs559653080, COSV55818179, COSV99904509; called by muse, mutect2, varscan2
- CCNL2 | c.1452G>T p.K484N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV101275679; called by muse, mutect2
- CCNT1 | c.1886G>T p.S629I | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as rs1173622086, COSV99980716; called by muse, varscan2
- CCPG1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100197157; called by muse, mutect2, varscan2
- CCR3 | c.768T>G p.N256K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100656498; called by muse, mutect2, varscan2
- CCR3 | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100656327, COSV100656500; called by muse, mutect2, varscan2
- CCRL2 | c.645T>G p.I215M | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100645027; called by muse, mutect2, varscan2
- CCSER2 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99825903; called by muse, varscan2
- CCT4 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs771250995, COSV101075184; called by muse, mutect2, varscan2
- CCZ1B | c.730T>G p.L244V | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as COSV100367843; called by muse, mutect2, varscan2
- CD163 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63133576; called by muse, mutect2, varscan2
- CD164L2 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138011471; called by muse, mutect2, varscan2
- CD180 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV56516673, COSV99842027; called by muse, mutect2, varscan2
- CD19 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV100218115; called by muse, mutect2
- CD200R1L | c.230G>A p.C77Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101236582; called by muse, mutect2, varscan2
- CD244 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV100458496; called by muse, mutect2, varscan2
- CD2BP2 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.149); catalogued as COSV99977078; called by muse, mutect2
- CD33 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99220379; called by muse, mutect2, varscan2
- CD48 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as COSV100924228; called by muse, mutect2, varscan2
- CD9 | c.456C>A p.C152* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV99152941; called by muse, mutect2, varscan2
- CD99L2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100692217; called by muse, mutect2, varscan2
- CDADC1 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99212555; called by muse, mutect2, varscan2
- CDAN1 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100661301; called by muse, mutect2, varscan2
- CDC20B | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99696879; called by muse, mutect2
- CDC27 | c.800G>T p.S267I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV99294810; called by muse, mutect2, varscan2
- CDC37L1 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV101116530, COSV101116613; called by muse, mutect2, varscan2
- CDC42BPB | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV100775424; called by muse, mutect2, varscan2
- CDC45 | c.989A>G p.Q330R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.167); catalogued as rs1429579611, COSV99596649; called by muse, mutect2, varscan2
- CDC73 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66467016; called by muse, mutect2, varscan2
- CDCA7L | c.1163A>G p.Y388C | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100179165; called by muse, mutect2, varscan2
- CDH11 | c.1922G>T p.R641I | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99218266; called by muse, mutect2, varscan2
- CDH11 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs776736292, COSV51766937; called by muse, mutect2, varscan2
- CDH13 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs762601185, COSV99225621; called by muse, mutect2, varscan2
- CDH16 | c.1794C>A p.F598L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV100233862; called by muse, mutect2, varscan2
- CDH17 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as rs777904623, COSV99217407; called by muse, mutect2, varscan2
- CDH18 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV99934557; called by muse, mutect2, varscan2
- CDH2 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52298008, COSV99296788; called by muse, mutect2, varscan2
- CDH23 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.047); catalogued as COSV99820787; called by muse, mutect2, varscan2
- CDH6 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV99419074; called by muse, mutect2, varscan2
- CDH7 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59898012; called by muse, mutect2, varscan2
- CDH8 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as rs1179259076, COSV100181360, COSV54910550; called by muse, mutect2, varscan2
- CDHR3 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1013945866, COSV100488314; called by muse, mutect2, varscan2
- CDIN1 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.719); catalogued as COSV100589787; called by muse, mutect2, varscan2
- CDK4 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99225989; called by muse, mutect2, varscan2
- CDK5 | c.846G>T p.Q282H | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.369); catalogued as COSV99876901; called by muse, mutect2
- CDK5RAP2 | c.3103A>G p.R1035G | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100575415; called by muse, mutect2, varscan2
- CDK5RAP2 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100575417; called by muse, mutect2, varscan2
- CDK5RAP3 | c.983C>T p.T328I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100621152; called by mutect2, varscan2
- CDKN2AIP | c.1387C>A p.H463N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100187614; called by muse, mutect2, varscan2
- CDR2L | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as rs1433577650, COSV61501732; called by muse, mutect2, varscan2
- CDRT1 | c.1723G>T p.G575* | Nonsense Mutation (SNP) | VAF 18/133 reads (14%) | catalogued as COSV100599866; called by muse, mutect2, varscan2
- CDRT15 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs767030980, COSV101415140; called by muse, mutect2, varscan2
- CDV3 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as COSV99394251; called by muse, mutect2, varscan2
- CDX2 | c.713G>A p.R238K | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101122675; called by muse, mutect2, varscan2
- CEACAM20 | c.1499C>T p.T500I | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV100386872; called by muse, mutect2, varscan2
5,860 further variants in this file (4,191 protein-altering or splice-affecting, 1,518 silent, 151 other) are not listed here.
